Gene-level copy-number profile of tumor specimen ALCH-B48P-TTP1-A from ALCHEMIST case ALCH-B48P, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.4 years (20,950 days).
Specimen ALCH-B48P-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file eacc9b60-c493-4e7b-8afd-00483dd3ee08.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B48P-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/03cd7ae9-9efe-4f62-bd0b-d428872445b3

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 160; copy number 1: 29,701; copy number 2: 23,071; copy number 3: 5,205; copy number 4: 247; copy number 5: 7; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 160 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:46,742,092–46,750,891, 1 gene (within-gene range 0–1): PRSS45P.
- chr3:46,753,045–46,798,390, 2 genes (within-gene range 0–1): PRSS43P, AC109583.2.
- chr3:49,121,114–49,191,858, 5 genes: LAMB2, LAMB2P1, CCDC71, KLHDC8B, C3orf84.
- chr4:13,540,830–13,547,801, 2 genes: NKX3-2, LINC01096.
- chr5:8,717,684–8,717,883, 1 gene: AC091932.4.
- chr5:133,196,455–136,969,306, 100 genes (within-gene range 0–1) (broad region; genes not listed).
- chr6:107,697,299–107,700,218, 1 gene: AL096816.1.
- chr9:41,131,306–41,701,096, 21 genes (within-gene range 0–1): CBWD6, MIR4477A, RNA5SP530, AL845472.1, PTGER4P2-CDK2AP2P2, CDK2AP2P1, MYO5BP1, AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70, RN7SL565P, AL591926.7, AL591926.6, AL591926.5, AL591926.2, FAM242F, Y_RNA, AL591926.1, AL591926.4.
- chr9:64,486,164–64,498,745, 3 genes: CNN2P3, GXYLT1P6, AL773524.1.
- chr9:64,810,865–64,836,341, 2 genes: BNIP3P4, AL359955.1.
- chr9:133,152,948–133,163,933, 1 gene: GBGT1.
- chr16:2,119,207–2,136,129, 4 genes (within-gene range 0–2): AC009065.3, Y_RNA, MIR4516, MIR3180-5.
- chr16:14,363,109–14,418,908, 2 genes: LINC02130, AC040173.1.
- chr16:78,825,281–79,110,882, 10 genes (within-gene range 0–1): RPS3P7, AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2, AC009145.4, AC009145.3, AC009145.1, AC009145.2.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:78,845,345–78,846,868, 2 genes: AC022966.2, RPL9P29.
- chr17:78,855,478–78,855,844, 1 gene (within-gene range 0–1): AC022966.1.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 5,461 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,352,397–8,848,921, 2 genes, copy number 3 (within-gene range 2–3): RERE, RERE-AS1.
- chr1:8,750,430–8,807,051, 5 genes, copy number 3: RPL7P11, RPL7P7, Y_RNA, AL357552.1, AL357552.2.
- chr1:10,210,570–10,381,603, 4 genes, copy number 3: KIF1B, AL358013.1, RNU6-37P, RN7SL731P.
- chr1:23,303,771–23,344,336, 1 gene, copy number 3: HNRNPR.
- chr1:162,069,691–162,370,475, 2 genes, copy number 3 (within-gene range 2–3): NOS1AP, AL450163.1.
- chr1:162,316,852–180,890,279, 363 genes, copy number 3 (broad region; genes not listed).
- chr1:180,972,712–248,937,043, 1,318 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr3:128,693,669–128,825,942, 1 gene, copy number 3 (within-gene range 2–3): RAB7A.
- chr3:128,764,466–128,799,201, 3 genes, copy number 3: FTH1P4, RN7SL698P, RPS15AP16.
- chr3:130,048,143–130,055,920, 1 gene, copy number 4: AC083906.4.
- chr5:58,198–1,851,497, 65 genes, copy number 4–6 (broad region; genes not listed).
- chr5:150,400,041–150,796,734, 12 genes, copy number 3–4 (within-gene range 2–4): CD74, RPS14, NDST1-AS1, NDST1, SYNPO, AC011383.1, AC008453.2, MYOZ3, AC008453.1, RBM22, DCTN4, SMIM3.
- chr6:391,752–60,546,660, 1,478 genes, copy number 3–4 (broad region; genes not listed).
- chr6:61,574,328–63,779,336, 23 genes, copy number 3 (within-gene range 1–3): MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr7:37,032–2,844,308, 74 genes, copy number 3 (broad region; genes not listed).
- chr7:101,815,904–102,592,444, 32 genes, copy number 3 (within-gene range 2–3): CUX1, AC005096.1, AC005072.1, AC005086.2, AC005086.5, AC005086.4, AC005086.3, AC005086.1, AC005088.1, SH2B2, MIR4285, AC091390.1, Y_RNA, PMS2P12, SPDYE6, PRKRIP1, AC091390.3, AC091390.2, MIR548O, AC073517.1, ORAI2, ALKBH4, LRWD1, MIR5090, MIR4467, POLR2J, RASA4B, POLR2J3, UPK3BL2, AC093668.1, SPDYE2, POLR2J3.
- chr8:39,451,045–39,522,852, 1 gene, copy number 3: ADAM3A.
- chr8:41,426,655–42,555,195, 36 genes, copy number 3: SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19.
- chr8:43,246,755–144,393,242, 1,469 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr10:14,061–4,848,062, 68 genes, copy number 3 (broad region; genes not listed).
- chr11:35,579,430–36,697,867, 23 genes, copy number 4–5: AL135934.1, FJX1, AL138812.1, TRIM44, KRT18P14, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1, COMMD9, PRR5L, AC087277.1, AC087277.2, AC009656.1, TRAF6, AC061999.1, RAG1, RAG2, IFTAP, AC104042.1.
- chr14:36,677,921–37,172,606, 1 gene, copy number 3 (within-gene range 2–3): SLC25A21.
- chr14:36,952,309–37,552,361, 6 genes, copy number 3: MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P.
- chr14:75,013,769–75,136,930, 7 genes, copy number 3 (within-gene range 2–3): MLH3, RNU6-689P, ACYP1, ZC2HC1C, NEK9, HIF1AP1, AL049780.2.
- chr14:103,733,195–105,669,843, 77 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr14:105,785,505–105,845,678, 2 genes, copy number 3 (within-gene range 2–3): ATP6V1G1P1, IGHD.
- chr14:105,890,084–105,896,577, 6 genes, copy number 3 (within-gene range 2–3): AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16.
- chr17:35,578,046–35,726,413, 1 gene, copy number 3 (within-gene range 1–3): AP2B1.
- chr17:35,713,791–41,715,969, 303 genes, copy number 3 (broad region; genes not listed).
- chr17:45,393,902–45,434,421, 1 gene, copy number 3 (within-gene range 1–3): ARHGAP27.
- chr17:45,435,900–46,028,334, 26 genes, copy number 3 (within-gene range 1–3): PLEKHM1, AC091132.2, MIR4315-1, LRRC37A4P, Metazoa_SRP, AC091132.3, AC091132.1, AC091132.4, AC091132.5, RDM1P1, DND1P1, AC126544.2, AC126544.1, MAPK8IP1P2, RPS26P8, LINC02210, LINC02210-CRHR1, AC217774.1, AC217774.2, CRHR1, MAPT-AS1, SPPL2C, MAPT, MAPT-IT1, CR936218.2, Metazoa_SRP.
- chr17:52,390,515–52,987,652, 3 genes, copy number 3: LINC01982, LINC02089, LINC02876.
- chr17:71,011,997–73,312,005, 31 genes, copy number 3–4: AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1, ATG12P1, POLR3KP2, AC097641.1, SSTR2, COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L, CDC42EP4.
- chr17:76,624,761–76,643,786, 1 gene, copy number 3: ST6GALNAC1.
- chr18:12,056,676–12,057,822, 1 gene, copy number 6: AP002414.1.
- chr19:782,755–893,218, 10 genes, copy number 3: LINC01836, PTBP1, MIR4745, PLPPR3, MIR3187, AZU1, PRTN3, ELANE, CFD, MED16.
- chr21:43,107,942–43,168,646, 1 gene, copy number 4 (within-gene range 1–5): AP001631.2.
- chr21:43,140,523–43,172,805, 3 genes, copy number 3–5: FRGCA, AP001631.1, CRYAA.

Autosomal genes at a single copy (total copy number 1): 27,357. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
